Gene-level copy-number profile of tumor specimen TCGA-CZ-5451-01A from TCGA case TCGA-CZ-5451, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage II; Tumor grade: G3; Age at diagnosis: 74.8 years (27,312 days).
Specimen TCGA-CZ-5451-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-KIRC.95ac7c42-5087-4ca9-8fc6-a9d0819a8537.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-CZ-5451-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/57bf8ccd-db57-439a-9bbb-8f421c16dc25

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 5,606; copy number 2: 51,229; copy number 3: 2,985.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-CZ-5451-01A-01D-1499-01): tumor purity 0.63, ploidy 1.99, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 3,185. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
